Somatic mutation profile of tumor specimen TCGA-IB-AAUW-01A (aliquot TCGA-IB-AAUW-01A-12D-A38G-08) from TCGA case TCGA-IB-AAUW, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.8 years (23,306 days).
Specimen TCGA-IB-AAUW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5987815-d39b-4035-a6e5-42225bafd80b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUW-10A (Blood Derived Normal), aliquot TCGA-IB-AAUW-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c53d85-0b97-43dc-b903-385a69373e1c

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.3228T>C p.Y1076= (on ENST00000445061 / NM_138615.3; = p.Y1037= on NM_014966.3) | Silent (SNP) | VAF 14/309 reads (5%) | catalogued as COSV99276162; called by muse, mutect2
